Somatic mutation profile of tumor specimen TCGA-36-2544-01A (aliquot TCGA-36-2544-01A-01D-1526-09) from TCGA case TCGA-36-2544, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.5 years (21,384 days).
Specimen TCGA-36-2544-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d039234-f4a7-41c8-8713-0a865718dd07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-36-2544-10A (Blood Derived Normal), aliquot TCGA-36-2544-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/770aa02e-f3a3-45d3-a774-6006ad8e4741

The open-access MAF lists 70 somatic variants for this specimen: 56 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 13, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.981_982del p.C328* | Frame Shift Del (DEL) | VAF 100/139 reads (72%) | catalogued as rs80357772; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.294_297del p.S99Rfs*23 | Frame Shift Del (DEL) | VAF 21/33 reads (64%) | catalogued as rs730882015; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC10 | c.577G>C p.G193R (on ENST00000372530 / NM_001198934.2; = p.G150R on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.056); catalogued as COSV55084981, COSV55092204; called by muse, mutect2, varscan2
- ABCC10 | c.4127G>C p.G1376A (on ENST00000372530 / NM_001198934.2; = p.G1348A on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/302 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs1196526791, COSV99767082; called by muse, mutect2
- ACSBG1 | c.439A>G p.K147E | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV51903679; called by muse, mutect2, varscan2
- AHNAK | c.4137C>A p.H1379Q | Missense Mutation (SNP) | VAF 414/1325 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.164); catalogued as COSV57205168; called by muse, mutect2, varscan2
- ATP2B2 | c.745C>A p.R249S | Missense Mutation (SNP) | VAF 239/551 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as COSV59490646, COSV59499981; called by muse, mutect2, varscan2
- BANK1 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 52/59 reads (88%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as COSV59839014; called by muse, mutect2, varscan2
- BCR | c.2464G>C p.E822Q | Missense Mutation (SNP) | VAF 134/163 reads (82%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV59927837; called by muse, mutect2, varscan2
- CBLN1 | c.85G>T p.V29L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1166700766, COSV54653446, COSV54654056; called by muse, mutect2, varscan2
- CCDC197 | c.218T>A p.V73E | Missense Mutation (SNP) | VAF 85/179 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV58939151; called by muse, mutect2, varscan2
- CHI3L2 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV63873441; called by muse, mutect2, varscan2
- CPT1B | c.2176A>G p.I726V | Missense Mutation (SNP) | VAF 165/194 reads (85%) | SIFT tolerated (0.1); PolyPhen benign (0.192); catalogued as COSV56415329; called by muse, mutect2, varscan2
- EXPH5 | c.2468C>G p.P823R | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV56199323; called by muse, mutect2, varscan2
- FAM120B | c.134C>A p.A45D | Missense Mutation (SNP) | VAF 181/233 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53001764, COSV53008633; called by muse, mutect2, varscan2
- FAM120C | c.1470C>A p.S490R | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.499); catalogued as COSV60257746; called by muse, mutect2, varscan2
- FASTK | c.1268C>G p.T423S | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.608); catalogued as COSV52539308; called by muse, mutect2, varscan2
- GATAD2A | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs760826335, COSV53067156; called by muse, mutect2, varscan2
- GCH1 | c.500A>T p.K167I | Missense Mutation (SNP) | VAF 311/498 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54301280; called by muse, mutect2, varscan2
- HOXC13 | c.775C>A p.R259S | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54498165, COSV54499425; called by muse, mutect2, varscan2
- HPS1 | c.868-1G>A p.X290_splice | Splice Site (SNP) | VAF 90/98 reads (92%) | catalogued as COSV57266685; called by muse, mutect2, varscan2
- INHBA | c.888G>T p.Q296H | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.796); catalogued as COSV54219801; called by muse, mutect2, varscan2
- KMT2C | c.12619G>C p.G4207R | Missense Mutation (SNP) | VAF 194/266 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51340401; called by muse, mutect2, varscan2
- KPRP | c.1727G>A p.S576N | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.215); catalogued as COSV64221081, COSV64221559; called by muse, mutect2, varscan2
- L3HYPDH | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54198494; called by muse, mutect2, varscan2
- LRP8 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.713); catalogued as COSV100036324; called by muse, mutect2
- MDC1 | c.1087G>C p.A363P | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV64523480, COSV64524968; called by muse, mutect2, varscan2
- MEAF6 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 208/731 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs966763063, COSV56162538; called by muse, mutect2, varscan2
- MTCL1 | c.3208C>T p.P1070S (on ENST00000306329 / NM_001378206.1; = p.P751S on NM_015210.4) | Missense Mutation (SNP) | VAF 89/198 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV60403755; called by muse, mutect2, varscan2
- MYOCD | c.294G>C p.K98N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV58498157; called by muse, mutect2, varscan2
- MYOD1 | c.693C>A p.Y231* | Nonsense Mutation (SNP) | VAF 34/40 reads (85%) | catalogued as COSV51452794; called by muse, mutect2, varscan2
- NLGN1 | c.376T>A p.L126M | Missense Mutation (SNP) | VAF 32/624 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV100849135; called by muse, mutect2
- OR5AK2 | c.507C>A p.C169* | Nonsense Mutation (SNP) | VAF 159/337 reads (47%) | catalogued as rs1434875822, COSV58803887; called by muse, mutect2, varscan2
- OR7A5 | c.337T>G p.F113V | Missense Mutation (SNP) | VAF 120/303 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); catalogued as COSV59234190; called by muse, mutect2, varscan2
- P2RX3 | c.951C>A p.N317K | Missense Mutation (SNP) | VAF 253/603 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV54441625; called by muse, mutect2, varscan2
- PLCH1 | c.1193T>A p.I398N (on ENST00000340059 / NM_001130960.2; = p.I410N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 166/175 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV58188814; called by muse, mutect2, varscan2
- PPARGC1B | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV58526702; called by muse, mutect2, varscan2
- PRC1 | c.1672G>T p.G558C | Missense Mutation (SNP) | VAF 158/384 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs201777744; called by muse, mutect2, varscan2
- PRR23B | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 18/251 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.696); catalogued as COSV61494936; called by muse, mutect2
- PTPRO | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 89/194 reads (46%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.039); catalogued as COSV55504354, COSV55519530; called by muse, mutect2, varscan2
- RNF17 | c.881A>G p.E294G | Missense Mutation (SNP) | VAF 105/354 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV55034962; called by muse, mutect2, varscan2
- RPE65 | c.1390G>C p.D464H | Missense Mutation (SNP) | VAF 109/369 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as COSV52013656; called by muse, mutect2, varscan2
- RPGR | c.186C>G p.N62K | Missense Mutation (SNP) | VAF 165/391 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58832833; called by muse, mutect2, varscan2
- SAMD9L | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 153/366 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV59079942; called by muse, mutect2, varscan2
- SMUG1 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 92/205 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54538825; called by muse, mutect2, varscan2
- STAB2 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 214/485 reads (44%) | catalogued as rs149696858; called by muse, mutect2, varscan2
- STARD8 | c.2237G>C p.S746T | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.084); catalogued as COSV99366643; called by muse, mutect2
- SYNJ1 | c.740G>C p.S247T | Missense Mutation (SNP) | VAF 112/298 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59144839; called by muse, mutect2, varscan2
- TCERG1 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57034199; called by muse, mutect2, varscan2
- TLR6 | c.2333G>C p.R778T | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV67935011; called by muse, mutect2, varscan2
- TMC1 | c.1189G>T p.D397Y | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV99919190; called by muse, mutect2
- USP54 | c.3087G>C p.K1029N | Missense Mutation (SNP) | VAF 73/282 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV60440080; called by muse, mutect2, varscan2
- ZNF232 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 109/122 reads (89%) | catalogued as COSV51502568; called by muse, mutect2, varscan2
- ZWILCH | c.970A>G p.T324A | Missense Mutation (SNP) | VAF 69/278 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57178559; called by muse, mutect2, varscan2
- BMPR2 | c.2297_2314del p.T766_L771del | In Frame Del (DEL) | VAF 46/103 reads (45%) | called by mutect2, pindel, varscan2
- EFCAB13 | c.2017+2dup p.X673_splice | Splice Site (INS) | VAF 53/86 reads (62%) | called by mutect2, pindel, varscan2
- ALDH3A2 | c.48G>T p.R16= | Silent (SNP) | VAF 23/27 reads (85%) | catalogued as COSV51565754; called by muse, mutect2, varscan2
- ANKLE1 | c.1755C>T p.C585= (on ENST00000394458; = p.C531= on NM_152363.6) | Silent (SNP) | VAF 158/361 reads (44%) | catalogued as rs148939227; called by muse, mutect2, varscan2
- APOB | c.10344C>T p.T3448= | Silent (SNP) | VAF 94/103 reads (91%) | catalogued as rs13306193, COSV99264997; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- H2AC17 | c.309C>T p.I103= | Silent (SNP) | VAF 22/648 reads (3%) | catalogued as COSV58152021; called by muse, mutect2
- HTR6 | c.819G>A p.L273= | Silent (SNP) | VAF 199/218 reads (91%) | catalogued as COSV53869523; called by muse, mutect2, varscan2
- KCNQ5 | c.1419C>T p.F473= | Silent (SNP) | VAF 130/307 reads (42%) | catalogued as COSV59651324; called by muse, mutect2, varscan2
- MAGED1 | c.2109G>A p.G703= | Silent (SNP) | VAF 117/248 reads (47%) | catalogued as COSV58514626; called by muse, mutect2
- MAN2A2 | c.339G>A p.P113= | Silent (SNP) | VAF 48/79 reads (61%) | catalogued as rs745339983, COSV64637374; called by muse, mutect2, varscan2
- MUC17 | c.9549C>A p.T3183= | Silent (SNP) | VAF 350/804 reads (44%) | catalogued as rs750778755, COSV60281492; called by muse, mutect2, varscan2
- PCK1 | c.198C>T p.L66= | Silent (SNP) | VAF 122/231 reads (53%) | catalogued as COSV60126424; called by muse, mutect2, varscan2
- PPP1R21 | c.1128G>C p.A376= | Silent (SNP) | VAF 159/554 reads (29%) | catalogued as COSV54282233, COSV54290000; called by muse, mutect2, varscan2
- SPTB | c.4047G>T p.L1349= | Silent (SNP) | VAF 101/177 reads (57%) | catalogued as COSV67630116; called by muse, mutect2, varscan2
- STX12 | c.42C>T p.P14= | Silent (SNP) | VAF 54/60 reads (90%) | catalogued as rs1382954735, COSV64248993; called by muse, mutect2, varscan2
- LARS2 | c.*564C>T | 3'UTR (SNP) | VAF 80/201 reads (40%) | catalogued as COSV55525628; called by muse, mutect2, varscan2
